Gene-level copy-number profile of tumor specimen TCGA-W2-A7HB-01A from TCGA case TCGA-W2-A7HB, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 24.6 years (8,979 days).
Specimen TCGA-W2-A7HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.368c848f-2348-4f9f-94b4-34b472b188ed.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W2-A7HB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c78d48c2-2d28-42cf-ac5d-cf35ea5d8f51

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6,659; copy number 1: 6,910; copy number 2: 46,614; copy number 3: 52; copy number 4: 36; copy number 6: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W2-A7HB-01A-11D-A35H-01): tumor purity 0.34, ploidy 3.53, whole-genome doublings 1.

Caution: 4,272 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 4,272 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–147,003,618, 2,985 genes (broad region; genes not listed).
- chr3:114,314,500–115,147,288, 1 gene (within-gene range 0–1): ZBTB20.
- chr3:114,684,580–188,890,671, 1,285 genes (within-gene range 0–1) (broad region; genes not listed).
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,832,189, 2 genes, copy number 6: CFHR3, CFHR1.

Autosomal genes at a single copy (total copy number 1): 6,905. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
